Somatic mutation profile of tumor specimen ALCH-B27T-TTP1-A (aliquot ALCH-B27T-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B27T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 42.9 years (15,653 days).
Specimen ALCH-B27T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dcd1d16-577b-474c-bb90-6dd3fc1d0e2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B27T-NB1-A (Blood Derived Normal), aliquot ALCH-B27T-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfad5987-b970-4761-afa0-c71cf86cacb1

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 2, Intron 2, Silent 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KBTBD7 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 28/273 reads (10%) | catalogued as rs1407923076; called by muse, mutect2
- NCAPG2 | c.1265A>G p.K422R | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs1164520937; called by muse, mutect2
- TBC1D5 | c.889A>G p.I297V | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs985564080; called by muse, mutect2
- OR2W3 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PTTG1 | c.529+2T>A p.X177_splice | Splice Site (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- SPINK1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- RPE | c.630C>T p.I210= (on ENST00000359429 / NM_001318926.1; = p.I160= on NM_006916.2) | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- COPS3 | c.762+286G>T | Intron (SNP) | VAF 11/165 reads (7%) | called by muse, mutect2
- CPLANE1 | c.*3866T>G | 3'UTR (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- MMAB | c.*1150C>T | 3'UTR (SNP) | VAF 16/163 reads (10%) | catalogued as rs1023371210; called by muse, mutect2, varscan2
- PROSER1 | c.112-29C>G | Intron (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
